Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ADBL, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ADBL-TTM1-A (Metastatic).

[page 1 of 10]
Tissue Biopsy Scan -

+916

DOB: [REDACTED] AGE: [REDACTED] years sex: Male

MRN:
FIC:
ADMITTED:
PT LOCATION:

ADMITTING PROVIDER:
DISCHARGED:
PT TYPE:

Outpatient Procedure

+916

Surgical Pathology Report - Final

COLLECTED DATE / TIME RECEIVED DATE / TIME ACCESSION NUMBER

Clinical Information

Lung nodule, malignant melanoma

+916

Diagnosis

A. Right lung nodule, core biopsy:
Metastatic melanoma.

Comment

Molecular testing for BRAF mutations will be performed and the results will be issued in a separate report.

Specimen

A. Right lung nodule.

Gross Description

A. Received in formalin, labeled with the patient's name [REDACTED] and designated "right lung nodule", are multiple tan pieces of tissue measuring 0.5 x 0.2 x 0.1 cm in aggregate and is submitted entirely in one cassette for microscopic examination.

Microscopic Description

A microscopic examination has been performed and is reflected in the above diagnosis(es).

[page 2 of 10]
Tissue Biopsy Scan - [REDACTED] +644

SURG PATH FINAL REPORT

Status: Final

+646

Results

Patient Information

Patient Name [REDACTED] MRN [REDACTED] Sex [REDACTED] DOB [REDACTED] SSN [REDACTED]

Primary phone: [REDACTED]

Entry Date

+646

Component Results

Surg Path Clinical Information:
Groin melanoma.

Two sutures marks most inferior medial point with marking efferent apparently involved lymphatic, one suture marks most superior lateral point.

Surg Path Diagnosis:

A. "Right groin wide excision of melanoma with excision superficial node dissection":

Melanoma, recurrent/metastatic, involving dermis and subcutis, with lymphovascular invasion, see comment.

Melanoma present at the inferior/medial margin (slide A1).

Dermal scar.

B. "Additional superior margin from right groin extending over lower abdomen":

Negative for tumor, including one benign lymph node (0/1).

Surg Path Diagnosis:

Comment:

Surg Path Comment:

With regard to specimen A, multiple tumor nodules are present in the dermis and subcutis, not clearly representing lymph nodes.

BRAF mutation testing will be performed; please refer to the subsequent Molecular Diagnostics report for results.

Surg Path Specimen:

A. Right groin wide excision of melanoma with excision superficial node dissection

B. Additional superior margin from right groin extending over lower abdomen

Surg Path Gross:

A. Received in formalin, in a properly labeled container with the patient name and designated "right groin wide excision of melanoma with excision superficial node dissection", the specimen consists of an oriented, roughly triangular 12 x 8 cm portion of tan skin. Subcutaneous adipose tissue and lymph nodes extend from the medial-inferior border. Multiple darkly pigmented subcutaneous and dermal lesions are noted diffusely on the skin surface ranging from 0.2-0.5 cm. The suspected lesions terminate 2 cm from all margins. Multiple involved, darkly pigmented lymph nodes are present.

The lateral margin is inked yellow, the superior-medial margin is inked blue, the inferior at the medial margin is inked green, and the deep margin is inked black.

Cassette summary:

1. Suture designated lymphatic from inferior/medial margin of specimen
- 2-3. Dermal tumor from multiple sites
4. 3 lymph nodes
5. 2 lymph nodes arising within scar from previous sentinel node biopsy
- 6-13. One lymph node in each cassette

B. Received in formalin, in a properly labeled container with the patient name and designated "additional superior margin from right groin extending over lower abdomen", the specimen consists of an unoriented 5.5 x 1.2 cm ellipse of tan skin resected to a depth of 5 cm. No evidence of a skin surface lesion or scar is identified. The soft tissue resection margin is inked blue.

A 1.5 cm tan, focally indurated lymph node is retrieved from the subcutaneous tissue. No secondary lymph nodes are identified. The dermis is gray-white and homogeneous throughout.

Cassette summary:

- 1-2. Lymph node, sectioned
3. Samples of skin ellipse, full-thickness transverse sections that display unoriented margins

Surg Path Micro:

A microscopic examination has been performed and is reflected in the above diagnosis(es).

Lab Collection Information

Collection Date and Time

+644

Lab Information

[page 3 of 10]
Surgical Pathology Final Report

Temporary Copy

Page 1 of 2

Case [REDACTED]
Collected [REDACTED]
Ordered [REDACTED]

+0

CLINICAL INFORMATION

Spitz nevus, reexcision of atypical nevus.

DIAGNOSIS

A. Skin, site not specified, excision:

Malignant melanoma.

See case summary.

CASE SUMMARY FOR CUTANEOUS MELANOMA (Excisional Biopsy or Resection):

Tumor site: Right knee

Tumor size: 7 mm, greatest dimension

Macroscopic satellite nodule: Not identified

Histologic type: Nodular melanoma

Breslow tumor thickness: 3.0 mm

Clark level: IV

Ulceration: Present

Margins:

Peripheral margins: Uninvolved by invasive melanoma; 2 mm from closest margin

Deep margin: Uninvolved by invasive melanoma; 1.3 mm from deep margin

Mitotic rate: 18 mitoses/square mm

Microscopic satellites: Not identified

Lymphovascular invasion: Not identified

Perineural invasion: Not identified

Regression: Not identified

Tumor infiltrating lymphocytes: Not identified

Pathologic Staging (pTNM):

Primary tumor (pT): pT3b: Melanoma 2.0 to 4.0 mm in thickness, with ulceration

Regional lymph nodes (pN): pNX: Regional lymph nodes cannot be assessed

Distant metastasis (pM): pM: Not applicable

Additional pathologic findings: Adjacent dysplastic nevus with spitzoid features, extending to within 0.2 mm of the peripheral margin. Dermal scar consistent with previous biopsy site.

AJCC Staging (7th Edition): pT3b pNX pM not applicable

COMMENT

A properly controlled melanoma cocktail stain is positive, confirming the melanocytic nature of the lesion.

SPECIMEN

[page 4 of 10]
Surgical Pathology Final Report

Temporary Copy

Page 2 of 2

+0

Case: [REDACTED]

Collected: [REDACTED]

Ordered by: [REDACTED]

A. Wide excision, atypical nevus with regrowth.

GROSS DESCRIPTION

A. Received in formalin, labeled with the patient's name and designated " wide excision, atypical nevus with regrowth " is an unoriented ellipse of tan skin measuring 2 x 1.3 cm, excised to a depth of 0.2-0.3 cm. An ovoid somewhat eccentric 0.8 x 0.6-0.7 cm lesion with a dry crusty center and surrounding gray white rim is 0.2 cm from the nearest long axis and 0.7 cm from the nearest tip. The surrounding skin is dusky gray-brown and mottled encompassing a 1.3 x 1.2 cm area. The nearest long axis is inked blue and the opposite is inked green, and deep is inked black. The specimen is serially sectioned and entirely submitted. Ellipse tips are bisected. ESB4, with tips in 1 and 4

QC

[page 5 of 10]
CT Interp Only Thorax Abd+Pel w IV Contr

* Final Report *

Result Date: +611

Encounter info:

* Final Report *

Reason For Exam

recurrent melanoma

Findings

Examination: Interpretation only CT of the thorax, abdomen, and pelvis with intravenous contrast

Date: +611

History: Recurrent melanoma. Restaging.

Technique: CT of the chest, abdomen, and pelvis were performed at 3 mm intervals with intravenous and oral contrast. The CT is compared to the PET study from the same date.

Findings: CT of the chest shows the lungs to be clear without nodular opacities or infiltrates. No pleural or pericardial effusions are seen. No mediastinal or hilar adenopathy is identified.

CT the abdomen shows several tiny low-attenuation lesions in the liver. These are not hypermetabolic on PET and are near water density in attenuation. They probably represent incidental small hepatic cysts but are too small for accurate attenuation value measurement. The spleen is normal in size and contour. The adrenal glands are normal in size and appearance. The pancreas is normal in size and appearance. The kidneys are normal in size and show no hydronephrosis. No adenopathy is seen in the abdomen. No abnormalities of the abdominal bowel loops are seen.

CT of the pelvis shows no adenopathy. No abnormalities of the pelvic bowel loops are seen. The prostate gland is moderately enlarged and contains coarse calcifications. The urinary bladder is normal in contour. There are areas of nodularity in the right groin region with areas of focal skin thickening and areas of subcutaneous nodularity. The largest discrete nodules measure only approximately 8 mm in size. These correspond to mild to moderate metabolic activity on PET. The relatively low-level metabolic activity on PET is probably just due to the small subcentimeter size of each of the discrete nodular lesions.

No sclerotic or lytic bony lesions are identified.

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 6 of 10]
* Final Report *

Impression:

1. Focal areas of nodular skin thickening and focal subcutaneous nodules in the right groin region corresponding to areas of mild to moderately increased metabolic activity on PET. This corresponds to the site of the recently discovered metastatic involvement with small "peppercorn" like sites of skin and subcutaneous tissue which have developed in this area and were recently biopsied and found to be metastatic.
2. No other metastatic lesions are seen elsewhere in the chest, abdomen, or pelvis.
3. Scattered small low-attenuation lesions in the liver, not hypermetabolic on PET and most likely representing small scattered incidental hepatic cysts.

Signature Line

Completed Action List:

[page 7 of 10]
CT Multi Scan - [REDACTED] +895

Owned [REDACTED]

CT Thorax, Abd + Pelvis w IV Contrast [REDACTED]

* Final Report *

Result Type: CT Thorax, Abd + Pelvis w IV Contrast
Result Date: [REDACTED]
Result status: [REDACTED]
Result Title: [REDACTED]
Performed By: [REDACTED]
Verified By: [REDACTED]
Encounter info: [REDACTED]

* Final Report *

Reason For Exam

MALIGNANT MELANOMA OF THE LOWER LIMB

Findings

Examination: CT of the Chest, Abdomen and Pelvis with IV Contrast
Technique: Axial helical images are obtained from the thoracic inlet through the ischial tuberosities after the administration of 125 mL Isovue-370 intravenous contrast.

Examination Date: [REDACTED] +895
Comparison Exam: CT chest dated [REDACTED] PET/CT dated [REDACTED] and CT chest abdomen pelvis [REDACTED] +611 [REDACTED] +653 [REDACTED] +611

Clinical History: MALIGNANT MELANOMA OF THE LOWER LIMB

Findings:

CT of the Chest with IV Contrast:
There is interval resolution of the left lower lobe consolidation/pneumonia.

Several new discrete pulmonary nodules are present concerning for metastatic disease as follows:

Right upper lobe 6 mm image 164 of series 2
Right middle lobe 6 mm image 173 of series 2.
Basal right lower lobe 6 mm image 201 of series 2.
Several 3 to 4 mm nodules in the basal right lower lobe has in images 192 of series 2
Large 1 cm nodule basal left lower lobe image 183 of series 2.
Several small to 4 mm nodules in the peripheral left upper lobe.

No thoracic lymph node enlargement
No pleural effusions.
Heart size is within normal limits. No pericardial effusion.
Normal appearance of the aorta and central pulmonary arteries.
Central airways are patent without endobronchial lesions.
No axillary lymph node enlargement. No aggressive bone lesions or soft tissue

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 1 of 2
(Continued)

[page 8 of 10]
CT Thorax, Abd + Pelvis w IV Contrast [REDACTED]

* Final Report *

abnormalities in the chest wall.

CT of the Abdomen and Plevvis with IV Contrast:

No significant abnormalities in the solid abdominal organs including the liver, spleen, pancreas, kidneys and adrenal glands. A few small too small to characterize low-attenuation lesions in the liver under 1 cm in size are stable.

No abdominal lymph node enlargement and no free fluid in the abdomen.

Large and small bowels are unremarkable without dilatation or wall thickening or masses.

Normal caliber abdominal aorta.

There is skin thickening in the right groin with subcutaneous infiltration and soft tissue thickening just superficial to the sartorius and the femoral vessels. The extent of this thickening and ill-defined soft tissue mass has increased on the prior study. New surgical clips is seen in this location possibly from prior biopsy.

Impressions:

1. Several new discrete pulmonary nodules concerning for metastatic disease.

2. Increased skin thickening and ill-defined diffuse subcutaneous soft tissue mass in the right groin. New surgical clips are seen in this location and part of this abnormality may be postsurgical however progressive metastatic disease in this location must be considered.

Signature Line

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 2 of 2
(End of Report)

[page 9 of 10]
CT Thorax, Abd + Pelvis w IV Contrast

* Final Report *

+1615

Result Date:
Encounter info:

* Final Report *

Reason For Exam

melanoma number of mitoses

Findings

Examinations:

CT of the chest with intravenous contrast
CT of the abdomen with intravenous contrast
CT of the pelvis with intravenous contrast

Date: +1615
History: melanoma number of mitoses

Comparison: +1426
Technique:

Contrast: -- 125 mL Isovue-370
Scanning area: -- Lung apices to pubic symphysis
Series/Phases: -- Portal venous
Reconstructions: -- Transverse MIP (chest); sagittal and coronal

Findings:

CT chest with intravenous contrast:

There are no enlarged lymph nodes in the chest. There is no pleural fluid. A few small irregular densities in the lungs remain stable. No new findings are seen.

CT abdomen with intravenous contrast:

There are small hypodensities in the liver, unchanged from the prior study. The larger lesions are consistent with cysts. The smaller lesions are difficult to characterize but are likely cysts given their conspicuity for their small size as well as their stability over time. No new liver lesions are seen. The other solid organs of the abdomen have a normal CT appearance. Bowel loops are unremarkable. There is no free fluid or lymph node enlargement.

CT pelvis with intravenous contrast:

There is no free fluid. No enlarged lymph nodes are seen. Postoperative changes are again seen in the right groin. Bowel loops are unremarkable.

IMPRESSION:

Stable CT of the chest, abdomen, and pelvis

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 10 of 10]
CT Thorax Abd + Pelvis w IV Contrast

* Final Report *

Signature Line

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 93412b21-24a8-47ac-a043-d3359b406e07 (ER0309 ER-ADBL Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).